Gene-level copy-number profile of tumor specimen TCGA-BR-4267-01A from TCGA case TCGA-BR-4267, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 51.2 years (18,699 days).
Specimen TCGA-BR-4267-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.665696b0-2e69-4075-9ba4-e067e4f8d064.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4267-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/475190a9-2985-4846-a1b3-63ae7f532dc3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,627; copy number 2: 37,501; copy number 3: 9,088; copy number 4: 590; copy number 5: 5; copy number 6: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-4267-01A-01D-1130-01): tumor purity 0.75, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,413,716–241,802,133, 8 genes, copy number 6 (within-gene range 4–6): AL359764.2, AL359764.3, FH, KMO, OPN3, CHML, AL133390.1, WDR64.
- chr9:4,299,390–4,666,674, 5 genes, copy number 5 (within-gene range 4–5): AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1.

Autosomal genes at a single copy (total copy number 1): 10,240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
